Surgical pathology report (de-identified scan), TCGA case TCGA-61-2101, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2101-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

A, AFS) LEFT ADNEXA:

- MODERATELY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA OF THE LEFT OVARY WITH EXTENSION INTO LEFT
PARATUBAL TISSUE

NOTE: The tumor involves ovarian surface.

Source: NCI Genomic Data Commons file 1b461ccd-ce9b-4755-98ab-d168cfcfb312 (TCGA-61-2101.B9D85995-85DD-4B00-B93F-3387CD018475.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).